Somatic mutation profile of tumor specimen 0DVJOF from CCDI case PBCKNR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.9 years (681 days).
Specimen 0DVJOF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9268481c-6b16-4513-bff5-da9d445999a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVJNN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa2d88af-b930-4c49-87f0-cf071afd815e

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCK2 | c.915C>T p.L305= | Silent (SNP) | VAF 98/489 reads (20%) | catalogued as COSV50782724; called by muse, mutect2, varscan2
- SLC47A1 | c.854-21A>G | Intron (SNP) | VAF 78/298 reads (26%) | called by muse, mutect2, varscan2
